Somatic mutation profile of tumor specimen TARGET-10-PAPFZF-09A (aliquot TARGET-10-PAPFZF-09A-01D) from TARGET case TARGET-10-PAPFZF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,317 days).
Specimen TARGET-10-PAPFZF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60cfe268-fa8e-4da5-9f57-9de34514706e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPFZF-14A (Bone Marrow Normal), aliquot TARGET-10-PAPFZF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/563201f5-6cf3-4375-8b61-957bd806dcf8

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKR1B10 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 80/152 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.136); catalogued as rs757758746; called by muse, mutect2, varscan2
- H2BC17 | c.292G>C p.A98P | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- NCOR1 | c.4368_4369insA p.S1457Ifs*4 | Frame Shift Ins (INS) | VAF 62/85 reads (73%) | called by mutect2, pindel, varscan2
- USH2A | c.2845C>A p.L949M | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- DMD | c.6339A>T p.I2113= | Silent (SNP) | VAF 48/98 reads (49%) | called by muse, mutect2, varscan2
- DMD | c.201A>G p.G67= | Silent (SNP) | VAF 74/148 reads (50%) | called by muse, mutect2, varscan2
- SASH1 | c.3318C>T p.I1106= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs768146323; called by muse, mutect2, varscan2
- ZNF516 | c.1080C>T p.V360= | Silent (SNP) | VAF 51/84 reads (61%) | catalogued as rs376933533; called by muse, mutect2, varscan2
